Somatic mutation profile of tumor specimen MP2PRT-PASDIM-TMP1-A (aliquot MP2PRT-PASDIM-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASDIM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,207 days).
Specimen MP2PRT-PASDIM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06f15c2c-52fd-4b94-ad1d-2893a1586465.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASDIM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASDIM-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed0a4177-3263-4b2a-aab7-f17fafcae48c

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD3A | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 131/587 reads (22%) | catalogued as rs1308954605; called by muse, mutect2, varscan2
- LARP6 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 206/582 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs766894389; called by muse, varscan2
- NMNAT3 | c.206G>A p.R69Q (on ENST00000296202 / NM_001320512.1; = p.R32Q on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 240/510 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs889792534; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 26/409 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2
- RIN3 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 21/530 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.542); catalogued as rs1365394537, COSV53648133; called by muse, mutect2
- SETD1A | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 26/656 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV52691115; called by muse, mutect2
- CAD | c.3608T>C p.L1203P | Missense Mutation (SNP) | VAF 94/252 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTT | c.2775T>A p.H925Q | Missense Mutation (SNP) | VAF 109/333 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- IGHV1-69 | c.339_351delinsCTGGG p.Y114Wfs*? | Frame Shift Del (DEL) | VAF 47/111 reads (42%) | called by pindel, varscan2*
- IL1RAPL2 | c.959C>G p.S320* | Nonsense Mutation (SNP) | VAF 177/226 reads (78%) | called by muse, mutect2, varscan2
- KCNG1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 169/424 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KLF2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 274/657 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NCKAP5 | c.4436G>A p.C1479Y | Missense Mutation (SNP) | VAF 144/346 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NFIC | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 223/523 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ROBO2 | c.1907A>T p.D636V | Missense Mutation (SNP) | VAF 164/405 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- WDR87 | c.5103_5104insGCTCTCG p.Q1702Afs*45 | Frame Shift Ins (INS) | VAF 163/386 reads (42%) | called by mutect2, pindel*, varscan2
- ZNF316 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 237/502 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.357); called by muse, varscan2
- ZNF354A | c.110A>C p.N37T | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.089); called by muse, mutect2
- G3BP1 | c.1023A>G p.Q341= | Silent (SNP) | VAF 131/291 reads (45%) | catalogued as rs775299123; called by muse, mutect2, varscan2
- KMT5B | c.1824C>G p.G608= | Silent (SNP) | VAF 174/390 reads (45%) | called by muse, mutect2, varscan2
- PRG4 | c.3462G>A p.L1154= | Silent (SNP) | VAF 103/312 reads (33%) | called by muse, mutect2, varscan2
- SIN3A | c.2241G>A p.K747= | Silent (SNP) | VAF 102/258 reads (40%) | called by muse, mutect2, varscan2
- TACR2 | c.597C>T p.L199= | Silent (SNP) | VAF 107/285 reads (38%) | catalogued as COSV100964811, COSV64822066; called by muse, mutect2, varscan2
- TBC1D9 | c.2802C>T p.H934= | Silent (SNP) | VAF 132/323 reads (41%) | catalogued as rs554890813, COSV101464291; called by muse, varscan2
- CNTNAP3P2 | n.370G>A | RNA (SNP) | VAF 24/239 reads (10%) | catalogued as rs772166516; called by muse, mutect2, varscan2
